Somatic mutation profile of tumor specimen MP2PRT-PARSZZ-TMP1-A (aliquot MP2PRT-PARSZZ-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PARSZZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,499 days).
Specimen MP2PRT-PARSZZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 161f3623-042d-4e7a-95cf-e8a9ff7694a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARSZZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARSZZ-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4a260a2-d80c-41b9-84aa-aae9e990db43

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, 5'Flank 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA3 | c.2821G>A p.D941N | Missense Mutation (SNP) | VAF 148/384 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV60710826; called by muse, mutect2, varscan2
- HPGDS | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV99755489; called by muse, mutect2, varscan2
- SLC6A19 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 26/470 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs201070872; called by muse, mutect2
- TPSD1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 278/920 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); catalogued as rs370368331, COSV52974267; called by muse, mutect2, varscan2
- ARMT1 | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 102/241 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- IGKV2D-30 | chr2:89937674 TGGCCTCCCACA>CAGAGG | Missense Mutation (DEL) | VAF 61/190 reads (32%) | called by pindel, varscan2*
- NCOR1 | c.6017_6018insCCCCC p.T2007Pfs*44 | Frame Shift Ins (INS) | VAF 67/188 reads (36%) | called by mutect2, pindel, varscan2
- NRXN3 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 220/556 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PXDNL | c.3380T>C p.F1127S | Missense Mutation (SNP) | VAF 198/459 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRDV2 | chr14:22423024 CTACTGTGCCTGTGACACCCACCCTGCT>AGG | Missense Mutation (DEL) | VAF 40/56 reads (71%) | called by pindel, varscan2*
- UACA | c.1512G>T p.K504N | Missense Mutation (SNP) | VAF 91/243 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LARP1B | c.1605G>A p.E535= | Silent (SNP) | VAF 123/324 reads (38%) | called by muse, mutect2, varscan2
- NPC1L1 | c.708G>A p.L236= | Silent (SNP) | VAF 202/518 reads (39%) | called by muse, mutect2, varscan2
- SCN9A | c.4974C>T p.Y1658= (on ENST00000303354; = p.Y1647= on NM_002977.3) | Silent (SNP) | VAF 155/411 reads (38%) | catalogued as rs757858235, COSV57600994; ClinVar: likely benign; called by muse, mutect2, varscan2
- UTP18 | c.108C>T p.G36= | Silent (SNP) | VAF 391/890 reads (44%) | called by muse, mutect2, varscan2
- ZNF573 | c.1665A>G p.E555= (on ENST00000536220 / NM_001172692.1; = p.E497= on NM_152360.3) | Silent (SNP) | VAF 76/193 reads (39%) | called by muse, mutect2, varscan2
- AL353804.6 | n.68G>A | RNA (SNP) | VAF 17/479 reads (4%) | called by muse, mutect2
- C2orf16 | chr2:27571640 G>A | 5'Flank (SNP) | VAF 161/395 reads (41%) | catalogued as rs1446473701; called by muse, mutect2, varscan2
